Somatic mutation profile of tumor specimen TCGA-B4-5844-01A (aliquot TCGA-B4-5844-01A-11D-1669-08) from TCGA case TCGA-B4-5844, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 61.4 years (22,409 days).
Specimen TCGA-B4-5844-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57c9b505-856d-4d90-9c77-42f2b97306b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B4-5844-10A (Blood Derived Normal), aliquot TCGA-B4-5844-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48394867-9537-4cf4-9188-1a4875badc69

The open-access MAF lists 74 somatic variants for this specimen: 59 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 13, Frame Shift Del 9, Splice Site 4, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.5930C>G p.T1977R | Missense Mutation (SNP) | VAF 49/210 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63868784, COSV63869673, COSV63869920; called by muse, mutect2, varscan2
- ATP8B3 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs760435851, COSV59547235; called by muse, mutect2
- CD300A | c.104A>C p.Q35P | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60410861; called by muse, mutect2, varscan2
- CEACAM5 | c.1183A>C p.I395L | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV55754257; called by muse, mutect2, varscan2
- CEBPZ | c.1852G>A p.G618S | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.307); catalogued as rs1330274508, COSV52207920; called by muse, mutect2
- CFAP92 | c.952A>T p.I318F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV54048578; called by muse, mutect2
- CNTNAP3 | c.2332T>A p.Y778N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV52673499; called by muse, mutect2, varscan2
- CRHR1 | c.277T>G p.W93G | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53284363; called by muse, mutect2
- CYP4F11 | c.986-1G>T p.X329_splice | Splice Site (SNP) | VAF 21/67 reads (31%) | catalogued as COSV56128578, COSV99930956; called by muse, mutect2, varscan2
- CYP4F11 | c.986-2A>T p.X329_splice | Splice Site (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99930958; called by muse, mutect2, varscan2
- DNAH9 | c.11684C>T p.P3895L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV52370154; called by muse, mutect2, varscan2
- DPYD | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV60082433, COSV60084141; called by muse, mutect2, varscan2
- FAM168A | c.448G>T p.G150* (on ENST00000064778 / NM_001286050.2; = p.G141* on NM_015159.3) | Nonsense Mutation (SNP) | VAF 32/113 reads (28%) | catalogued as COSV50359687; called by muse, mutect2, varscan2
- G6PC | c.978del p.F327Sfs*6 | Frame Shift Del (DEL) | VAF 57/228 reads (25%) | catalogued as COSV53831329; called by mutect2, pindel, varscan2
- GNPTAB | c.1484T>G p.F495C | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV68449910; called by muse, mutect2, varscan2
- HYDIN | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV55496115; called by muse, mutect2, varscan2
- INTS12 | c.1309T>G p.S437A | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV60863323; called by muse, mutect2, varscan2
- IZUMO2 | c.567G>C p.L189F | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV53231151; called by muse, mutect2, varscan2
- LARP6 | c.1458G>T p.R486S | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV54581849; called by muse, mutect2, varscan2
- LRCH4 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59644244; called by muse, mutect2, varscan2
- LRP2 | c.13578C>G p.Y4526* | Nonsense Mutation (SNP) | VAF 28/123 reads (23%) | catalogued as COSV55568844; called by muse, mutect2, varscan2
- LY6E | c.19G>T p.V7L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52870204; called by muse, mutect2, varscan2
- MORF4L1 | c.976T>G p.L326V (on ENST00000331268 / NM_206839.2; = p.L287V on NM_006791.4) | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV58705461; called by muse, mutect2, varscan2
- NAA25 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV55707820; called by muse, mutect2, varscan2
- OR4K14 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59292095, COSV59293967; called by muse, mutect2, varscan2
- PCDH11X | c.2936C>T p.S979F | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53495316; called by muse, mutect2, varscan2
- PITX2 | c.865A>G p.K289E (on ENST00000354925 / NM_001204397.1; = p.K296E on NM_000325.6) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60742029; called by muse, mutect2, varscan2
- PRSS12 | c.477C>G p.D159E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as rs1560791081, COSV56609078; called by muse, mutect2, varscan2
- SCGB2A1 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 46/190 reads (24%) | catalogued as COSV55276752; called by muse, mutect2, varscan2
- SEC24B | c.3272C>A p.T1091K | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV54504700; called by muse, mutect2
- SIAE | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55013151, COSV55015632; called by muse, mutect2, varscan2
- SV2A | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64965620; called by muse, mutect2, varscan2
- TET1 | c.5560A>G p.T1854A | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV65382395; called by muse, mutect2, varscan2
- TEX11 | c.2303A>C p.H768P (on ENST00000344304; = p.H753P on NM_031276.3) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as COSV60236834; called by muse, mutect2, varscan2
- TFAP2D | c.238C>G p.H80D | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV50446305; called by muse, mutect2, varscan2
- TGM7 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs889702421, COSV71773075; called by muse, mutect2, varscan2
- TNRC6A | c.2903C>A p.T968K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV59368826; called by muse, mutect2, varscan2
- TRIM24 | c.2835G>C p.L945F (on ENST00000343526 / NM_015905.3; = p.L911F on NM_003852.4) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV58976726; called by muse, mutect2, varscan2
- TTLL6 | c.1589G>A p.R530Q (on ENST00000393382 / NM_001130918.3; = p.R223Q on NM_173623.3) | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs374777398; called by muse, mutect2, varscan2
- UBE3B | c.1208G>A p.S403N | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV55097221; called by muse, mutect2, varscan2
- XPO7 | c.991T>C p.C331R | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53018962; called by muse, mutect2, varscan2
- ZBTB33 | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 123/402 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58534850; called by mutect2, varscan2
- ZC3H12D | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66324839; called by muse, mutect2
- ZNF354B | c.599A>C p.N200T | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59367117; called by muse, mutect2, varscan2
- ZNF536 | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs568730030, COSV62831795; called by muse, mutect2, varscan2
- ANKFN1 | c.1551_1552dup p.T518Kfs*31 | Frame Shift Ins (INS) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- ATRX | c.3953del p.N1318Ifs*28 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel
- CSTF3 | c.1825del p.V609Cfs*11 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- DHX29 | c.2860_2864+20del p.X954_splice | Splice Site (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- NBR1 | c.643_644del p.I215Cfs*17 | Frame Shift Del (DEL) | VAF 58/252 reads (23%) | called by pindel, varscan2
- OR1L1 | c.72_75del p.R25Ifs*20 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel
- PBRM1 | c.645+1del p.X215_splice | Splice Site (DEL) | VAF 23/92 reads (25%) | called by mutect2, pindel, varscan2
- PDCD10 | c.214_215insAT p.V72Dfs*18 | Frame Shift Ins (INS) | VAF 31/116 reads (27%) | called by mutect2, varscan2*
- PDCD10 | c.211_213del p.S71del | In Frame Del (DEL) | VAF 29/117 reads (25%) | called by mutect2, pindel*, varscan2*
- PLXNB2 | c.644_647del p.T215Sfs*175 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- TRIM6 | c.1107_1111del p.G370Mfs*38 | Frame Shift Del (DEL) | VAF 34/124 reads (27%) | called by mutect2, pindel, varscan2
- TUT4 | c.3503del p.T1168Kfs*4 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- UBE2NL | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ZNF395 | c.884_885del p.V295Gfs*18 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by pindel, varscan2
- AHNAK2 | c.8295G>A p.A2765= | Silent (SNP) | VAF 70/247 reads (28%) | catalogued as rs529530064, COSV60918877; called by muse, mutect2, varscan2
- CHGB | c.294C>T p.S98= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100972950, COSV66761488; called by muse, mutect2, varscan2
- EPS15L1 | c.999C>T p.F333= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs746159746, COSV50173709; called by muse, mutect2, varscan2
- EYA2 | c.504C>A p.G168= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV100427092; called by muse, mutect2, varscan2
- KIAA1109 | c.13407G>A p.G4469= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV52687902; called by muse, mutect2, varscan2
- LRRC19 | c.552A>C p.L184= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV66259756; called by muse, mutect2, varscan2
- MAPKBP1 | c.2748C>A p.P916= (on ENST00000456763 / NM_001128608.2; = p.P910= on NM_014994.3) | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as COSV52966122; called by muse, mutect2
- MOV10L1 | c.978C>T p.D326= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV53177527; called by muse, mutect2, varscan2
- PAQR5 | c.594C>T p.L198= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as rs778022504, COSV61818053; called by muse, mutect2, varscan2
- PCDHGA2 | c.2379G>A p.A793= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV53915403, COSV54067778; called by muse, mutect2
- PGK2 | c.303C>T p.G101= | Silent (SNP) | VAF 11/134 reads (8%) | catalogued as rs549102825, COSV59163718; called by muse, mutect2
- RPL3 | c.618T>A p.P206= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV53366381; called by muse, mutect2, varscan2
- ZNHIT6 | c.1050C>G p.L350= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV65327670; called by muse, mutect2, varscan2
- DUSP13 | c.*279T>G | 3'UTR (SNP) | VAF 18/118 reads (15%) | catalogued as COSV100403579; called by mutect2, varscan2
- ELMO3 | c.1421-16T>C | Intron (SNP) | VAF 13/87 reads (15%) | catalogued as COSV58528093; called by muse, mutect2, varscan2
